FM case AD1370 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/4bd8613b-399f-4e93-8096-773002c8d751

Female, 71.4 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the female genital tract; metastasis biopsied or resected from the uterus. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
